Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A5EX, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A5EX-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					female	Caucasian (White)	Glioma		Brain, right frontal and temporal lobes	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Anaplastic oligodendroglioma	3	n/a	n/a	n/a	none	n/a	80
	Blood				female	Caucasian (White)	Glioma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-6-3
Oligodendroglioma,
anaplastic 945113
Site: Brain, Supratentorial
C71.0
4/4/13

Source: NCI Genomic Data Commons file b8359f93-92e7-4250-9634-c9a96165ed8a (TCGA-P5-A5EX.C2C64F70-4E69-4A52-97AE-04E0D8D627EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).